CCDI case PBBVRC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cbb3eca4-e28e-4d34-af8d-791fddf43a1f

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,276 days).

Biospecimens (3 samples)
- Sample 0DII39: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DII3L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DII4B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
